Surgical pathology report (de-identified scan), TCGA case TCGA-24-1844, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1844-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

Patient Name:

Address:

Service:

Accession #:

Location:

Taken:

Gender:

MRN :

Received:

DOB:

Hospital #:

Accessioned:

Patient Type:

Reported:

Physician(s):

DIAGNOSIS:

OVARIES, BILATERAL, BILATERAL SALPINGO-OOPHORECTOMY

-HIGH GRADE SEROUS ADENOCARCINOMA

-SEE COMMENT AND SYNOPTIC

FALLOPIAN TUBES, BILATERAL, BILATERAL SALPINGO-OOPHORECTOMY

-HIGH GRADE SEROUS ADENOCARCINOMA

-SEE COMMENT

SKIN AND SOFT TISSUE, UMBILICUS, EXCISION

-METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

LARGE INTESTINE, SIGMOID COLON, EXCISION

-EXTENSIVE SEROSAL AND SOFT TISSUE INVOLVEMENT BY HIGH GRADE SEROUS
ADENOCARCINOMA

SOFT TISSUE, "BLADDER PERITONEUM," EXCISION

-METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

OMENTUM, BIOPSY (FS1)

-METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

OMENTUM, EXCISION

-METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

PANCREAS, DISTAL, EXCISION

-PERIPANCREATIC SOFT TISSUE INVOLVEMENT BY METASTATIC HIGH GRADE SEROUS
ADENOCARCINOMA

LYMPH NODES, PERIPANCREATIC, EXCISION

-THREE LYMPH NODES WITH NO EVIDENCE OF MALIGNANCY

APPENDIX, EXCISION

-EXTENSIVE SEROSAL INVOLVEMENT BY METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

LARGE INTESTINE, DISTAL CECUM, EXCISION

-SEROSAL AND MUSCULARIS PROPRIA INVOLVEMENT BY METASTATIC HIGH GRADE SEROUS
ADENOCARCINOMA

[page 2 of 4]
TCGA-24-1844

SURGICAL PATHOLOGY REPORT

LARGE INTESTINE, "DONUTS," EXCISION
-NO EVIDENCE OF MALIGNANCY

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides(and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Brought to frozen 'BSO, pelvic tumor' consisting of a 65 gram 8 x 6 x 6 cm friable papillary-appearing tan-brown mass with attached fallopian tube portion. Portion of putative tube and tumor taken for Rest for permanents,"

FS: Omentum, biopsy

- "High grade adenocarcinoma, favor Mullerian," by

Microscopic Description and Comment:

Evaluation of the "BSO, pelvic tumor" specimen shows multiple matted fragments of ovarian tissue and fallopian tube all showing extensive involvement by high grade serous adenocarcinoma. Of particular note, the sections of fallopian tube show focal adenocarcinoma in situ within the tubal epithelium, finding that indicates that, formally, the disease in this case could be due to primary ovarian serous adenocarcinoma, primary tubal serous adenocarcinoma, or synchronous primary ovarian and tubal serous adenocarcinomas (by convention, in the absence of invasive disease arising within the tubal adenocarcinoma in situ, the tumor has been designated an ovarian primary and the corresponding synoptic completed). Clinical correlation is required.

History:

The patient is a with complex pelvic masses and a CA125 over 10,000. Operative procedure: Bilateral salpingo-oophorectomy and tumor debulking.

Specimen(s) Received:

A: OMENTUM
B: UMBILICUS
C: BSO PELVIC TUMOR
D: PELVIC TUMOR AND SIGMOID COLON
E: BLADDER PERITONEUM
F: OMENTUM
G: DISTAL PANCREAS, PARTIAL RESECTION
H: DISTAL CECUM AND APPENDIX
I: EEA DONUTS

Gross Description:

The specimen is received in nine formalin-filled containers, each labeled " ". The first is additionally labeled "omentum/FS1." It holds a piece of tan-brown fibroadipose tissue measuring 2 x 1.5 x 0.3 cm. At one end is a 1.0 x 0.5 x 0.3 cm tan nodule.

The second container is labeled "umbilicus." It holds an irregular piece of tan fibroadipose tissue measuring 3 x 1.5 x 0.7 cm. At one end is a firm 1.0 cm circumference nodule that has a trabeculated appearance on cut surface. Labeled

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

The third container is labeled "BSO, pelvic tumor." It holds a surgical specimen as described in the intraoperative consultation, measuring 8 x 6 x 6 cm. Within the main mass, the surface of which is disrupted by a tan neoplasm with papillary excrescences, two distinct ovaries cannot be discerned. Along one edge of the specimen is a 2.0 x 0.5 cm tubular structure, grossly consistent with fallopian tube. A putative fallopian tube is present (0.5 cm in length) along the opposite side. Labeled C1 to C4 - tumor in relation to serosa; C5 - fallopian tubes.

The fourth container is labeled "pelvic tumor and sigmoid colon." It holds an unoriented piece of large intestine measuring 25 cm in length. The serosal and mesenteric fat is studded with innumerable white nodules ranging in size from 0.1 to 1.5 cm. The colon is opened lengthwise to show a tan-brown mucosal folding pattern with no mucosal lesions. Six centimeters from one surgical margin, the serosal mass is impinging on the bowel lumen, and the luminal circumference narrows to 2 cm. The remainder of the luminal circumference is approximately 3.5 cm. The serosal fat is serially sectioned to show multiple white nodules consistent with numerous soft tissue tumor deposits. No definitive lymph nodes are identified. Also in the container is a separate fragment of fibroadipose tissue studded with tan-white tumor deposits measuring 7 x 5 x 3 cm. Sectioned to show a tan-white tumorous mass measuring 5 cm in greatest dimension. In the mid portion of this mass is a 0.3 cm luminal diameter containing fecal material. Labeled D1, D2 - large intestinal margin; D3, D4 - area of mucosa in serosa at area of narrowing; D5 - additional sections of bowel mucosa; D6 to D7 - serosal nodule; D8 to D9 - sections from separate fibroadipose tissue fragment.

The fifth container is labeled "bladder peritoneum." It holds a piece of fibrofatty tissue measuring 4 x 3 x 1.0 cm. The surface is studded with small (less than 0.2 cm) nodules.

The sixth container is labeled "omentum." It holds a piece of fibroadipose tissue measuring 15 x 15 x 3.0 cm. The fibroadipose tissue is studded with innumerable tan-white nodules, some of which coalesce and measure 5 cm in greatest dimension. The nodules are sectioned to show a solid tan-white cut surface.

The seventh container is labeled "distal pancreas." It holds a disrupted piece of fibroadipose tissue measuring 3.5 x 3 x 3.7 cm. Along one surface of this fibroadipose tissue is a 2 x 1 x 0.5 cm firm, lobulated tissue, grossly consistent with pancreas. Sectioned to show an unremarkable cut surface with no tumor grossly identified.

The eighth container is labeled "distal cecum and appendix." It holds two fragments of tan tissue. The first contains a 6 x 1 cm appendix. The mesoappendix is studded with multiple tan-white nodules, grossly consistent with involvement by the metastatic tumor. A 1.0 surgical suture at the line of resection is present distally within this specimen. The second tan tissue fragment measures 2 x 1 x 1 cm and has a 3.2 cm staple line of resection. Multiple tan-white nodules are present on the serosal surface. The largest measures 1.5 cm. These nodules are at the staple line of resection. Labeled H1 - appendix; H2 - additional tissue fragment.

The ninth container is labeled "EEA donuts, gross." It holds two mucosal donuts. The largest donut measures 2 x 1.5 x 0.5 cm and the mucosa has been everted and tan-brown with focal areas of pigmentation. The smaller donut measures 1 cm in diameter and also has focal mucosal hemorrhages.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)
See comment

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

[page 4 of 4]
CGA-24-1844

SURGICAL PATHOLOGY REPORT

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present
Metastatic involvement of the extrapelvic peritoneum is present
Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The total number of regional lymph nodes examined is 3
The total number of metastatically-involved lymph nodes is 0

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

T3c/N0/MX (Stage X)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 538746ee-e06e-4a73-a94f-bb11651911f3 (TCGA-24-1844.5FD30C3C-9734-40DD-B81E-AE3F364C8FA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).